Somatic mutation profile of tumor specimen TCGA-EB-A5SE-01A (aliquot TCGA-EB-A5SE-01A-11D-A30X-08) from TCGA case TCGA-EB-A5SE, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Nodular melanoma; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 73.8 years (26,965 days).
Specimen TCGA-EB-A5SE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4ea04f40-1608-49e6-925a-985ab6f6e863.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EB-A5SE-10A (Blood Derived Normal), aliquot TCGA-EB-A5SE-10A-01D-A30X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/02203e57-278f-4cc1-9f06-d256d9ed6a3f

The open-access MAF lists 351 somatic variants for this specimen: 221 protein-altering or splice-affecting, 122 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 210, Silent 122, Nonsense Mutation 6, RNA 5, Intron 3, Splice Site 3, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 121/163 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ZBTB20 | c.1847C>T p.S616F (on ENST00000474710 / NM_001164342.2; = p.S543F on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/41 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs879255635, CM166121, COSV61862279; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.6443C>T p.P2148L (on ENST00000272895 / NM_173076.3; = p.P1830L on NM_015657.3) | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1242372167, COSV55970091; called by muse, mutect2
- ABHD15 | c.1355C>T p.S452F | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as rs764326975, COSV100213043; called by muse, mutect2, varscan2
- ADAM29 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV63666452; called by muse, mutect2, varscan2
- ADAMTS19 | c.1845G>A p.M615I | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as rs1445363045, COSV50776468; called by muse, mutect2, varscan2
- ADAMTS8 | c.1751-1G>A p.X584_splice | Splice Site (SNP) | VAF 27/71 reads (38%) | catalogued as rs748267870, COSV57295947; called by muse, mutect2, varscan2
- ADGRL4 | c.1313C>T p.S438L | Missense Mutation (SNP) | VAF 49/81 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66064142; called by muse, mutect2, varscan2
- ADGRV1 | c.9826G>A p.E3276K | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0.078); catalogued as rs267600728, COSV67979812; called by muse, mutect2
- ADH1B | c.358C>A p.P120T | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV59297952; called by muse, mutect2, varscan2
- AHNAK | c.3721C>T p.P1241S | Missense Mutation (SNP) | VAF 120/327 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs368345679; called by muse, mutect2, varscan2
- AHNAK2 | c.6694C>T p.L2232F | Missense Mutation (SNP) | VAF 86/191 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1345185772, COSV60924771; called by muse, mutect2, varscan2
- AKR1C1 | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs782436589, COSV101080538; called by muse, mutect2, varscan2
- AKR7A3 | c.514T>A p.Y172N | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100853825; called by muse, mutect2, varscan2
- AKR7A3 | c.513G>A p.M171I | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.506); catalogued as rs1440932603, COSV64389420; called by muse, mutect2, varscan2
- ALDH1B1 | c.859G>A p.G287S | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs533684701, COSV66620393; called by muse, mutect2, varscan2
- ALK | c.2740G>A p.G914R | Missense Mutation (SNP) | VAF 25/39 reads (64%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.592); catalogued as rs1220052371, COSV66563644; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALPK2 | c.6254G>A p.G2085E | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV64495477; called by muse, mutect2, varscan2
- ARID1A | c.3784C>T p.R1262C | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs1202361373, COSV61384914; called by muse, mutect2, varscan2
- ASMTL | c.967G>A p.D323N | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.663); catalogued as COSV101187801, COSV67244799; called by muse, mutect2, varscan2
- AVIL | c.2029C>A p.Q677K | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV57683152; called by muse, mutect2, varscan2
- BEST3 | c.1033C>T p.P345S | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV58303952; called by muse, mutect2, varscan2
- BNC2 | c.1408C>T p.R470* | Nonsense Mutation (SNP) | VAF 34/83 reads (41%) | catalogued as COSV66153838; called by muse, mutect2, varscan2
- BRD3 | c.241A>G p.M81V | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1056218074, COSV57705537; called by muse, mutect2, varscan2
- BYSL | c.1216C>T p.R406W | Missense Mutation (SNP) | VAF 60/178 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs374880622; called by muse, mutect2, varscan2
- C10orf67 | c.338C>T p.S113F (on ENST00000323327; = p.S114F on NM_153714.3) | Missense Mutation (SNP) | VAF 10/11 reads (91%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV60114499; called by muse, mutect2, varscan2
- C1QTNF2 | c.547C>T p.P183S (on ENST00000393975; = p.P138S on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/150 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.859); catalogued as COSV67433145; called by muse, mutect2
- C5 | c.3616C>T p.R1206C | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs1402957355, COSV56324454; called by muse, mutect2, varscan2
- CAT | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as COSV53812470; called by muse, mutect2, varscan2
- CBX8 | c.1100C>T p.T367I | Missense Mutation (SNP) | VAF 61/134 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53937268; called by muse, mutect2, varscan2
- CCAR2 | c.1858C>T p.L620F | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT tolerated (0.68); PolyPhen benign (0.077); catalogued as rs1563925164, COSV52385961; called by muse, mutect2, varscan2
- CCDC158 | c.804G>A p.R268= | Splice Region (SNP) | VAF 16/43 reads (37%) | catalogued as rs761910070, COSV66356857; called by muse, mutect2, varscan2
- CCP110 | c.962C>T p.S321L | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as rs758917792, COSV66817675; called by muse, mutect2, varscan2
- CD44 | c.545C>T p.S182F | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.774); catalogued as rs141155638; called by muse, mutect2, varscan2
- CDH12 | c.1057C>T p.L353F | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.21); catalogued as COSV101203395, COSV66433160; called by muse, mutect2, varscan2
- CELSR1 | c.8153G>A p.G2718E | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV53090092, COSV53096574; called by muse, mutect2, varscan2
- CFAP54 | c.8063C>T p.S2688F | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.645); catalogued as rs537859109, COSV61571741; called by muse, mutect2, varscan2
- CFTR | c.1861G>A p.E621K | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.188); catalogued as COSV50080586; called by muse, mutect2, varscan2
- CHAT | c.1909G>A p.E637K | Missense Mutation (SNP) | VAF 57/66 reads (86%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.919); catalogued as rs777684375, COSV60330144; called by muse, mutect2, varscan2
- CHD8 | c.5542C>T p.H1848Y (on ENST00000646647 / NM_001170629.2; = p.H1569Y on NM_020920.4) | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV63037260; called by muse, mutect2, varscan2
- CHRNA10 | c.670C>T p.P224S | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.98); catalogued as COSV99167224; called by muse, mutect2, varscan2
- CHRNA9 | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.721); catalogued as rs775085099, COSV59573670; called by muse, mutect2, varscan2
- CHST1 | c.92T>A p.F31Y | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.047); catalogued as COSV57324984; called by muse, mutect2, varscan2
- CIB3 | c.415G>A p.G139R | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.143); catalogued as rs200526470, COSV54166412; called by muse, mutect2, varscan2
- CNNM3 | c.2048C>T p.T683I | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as rs776592449, COSV59709743; called by muse, mutect2, varscan2
- CYP4F2 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as rs868834988, COSV50000964; called by muse, mutect2, varscan2
- DAG1 | c.919C>T p.P307S | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.841); catalogued as COSV58183345; called by muse, mutect2, varscan2
- DGKB | c.2023G>A p.G675R | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51792886; called by muse, mutect2, varscan2
- DNAH5 | c.9643G>A p.E3215K | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.081); catalogued as COSV54243308; called by muse, mutect2
- DNAH5 | c.1873G>A p.G625R | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54243314; called by muse, mutect2, varscan2
- DNAH7 | c.8839G>C p.D2947H | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.671); catalogued as COSV56778282; called by muse, mutect2, varscan2
- DNAI1 | c.1010C>T p.A337V | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as rs267602217, COSV54283453; called by muse, mutect2, varscan2
- DPP6 | c.488G>A p.G163E (on ENST00000377770 / NM_001364500.2; = p.G101E on NM_001936.5) | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59635260; called by muse, mutect2
- DSC3 | c.1334G>A p.R445K | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as COSV64574528; called by muse, mutect2, varscan2
- EHMT2 | c.1687C>T p.P563S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.186); catalogued as rs377615321; called by muse, mutect2
- ELMO3 | c.100A>G p.T34A | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs1401304254, COSV62607362; called by muse, mutect2, varscan2
- ELP1 | c.820C>T p.L274F | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV65899180; called by muse, mutect2, varscan2
- ENGASE | c.2131C>T p.R711C | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs778361842, COSV56137086; called by muse, mutect2, varscan2
- EP300 | c.1664C>T p.P555L | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.066); catalogued as rs1205592710, COSV54340969; called by muse, mutect2, varscan2
- EP400 | c.2015C>T p.P672L | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.55); catalogued as COSV57781714; called by muse, mutect2, varscan2
- EPB41L4B | c.2371G>A p.E791K | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.952); catalogued as rs370880343; called by muse, mutect2, varscan2
- ERAP1 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.348); catalogued as COSV57090427; called by muse, mutect2, varscan2
- ERF | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 31/183 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as COSV55897012; called by muse, mutect2, varscan2
- ETNK2 | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV65821133; called by muse, mutect2, varscan2
- FABP6 | c.110G>A p.R37K | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV67436744, COSV67437527; called by muse, mutect2, varscan2
- FAM50B | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.686); catalogued as COSV66655095; called by muse, mutect2, varscan2
- FAT3 | c.11525G>A p.G3842E | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs746711467, COSV53094184; called by muse, mutect2, varscan2
- FBN2 | c.6870G>C p.K2290N | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.596); catalogued as COSV52534745; called by muse, mutect2, varscan2
- FLG2 | c.3488C>T p.S1163L | Missense Mutation (SNP) | VAF 106/170 reads (62%) | SIFT tolerated (0.12); PolyPhen benign (0.175); catalogued as COSV66171465; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1819C>T p.R607* | Nonsense Mutation (SNP) | VAF 19/40 reads (48%) | catalogued as rs201857576, COSV100437520; called by muse, mutect2, varscan2
- FREM2 | c.2089G>A p.D697N | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV54846800; called by muse, mutect2, varscan2
- GALNT13 | c.562T>G p.L188V | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV67232576; called by muse, mutect2, varscan2
- GALNT18 | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.961); catalogued as rs201734768, COSV57154417, COSV57156274; called by muse, mutect2, varscan2
- GFI1B | c.510+1G>A p.X170_splice | Splice Site (SNP) | VAF 13/31 reads (42%) | catalogued as COSV59746297; called by muse, mutect2, varscan2
- GIGYF2 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as COSV65252260; called by muse, mutect2, varscan2
- GLG1 | c.3521G>A p.R1174Q | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs770757693, COSV52672122; called by muse, mutect2, varscan2
- GPC3 | c.1454A>T p.D485V | Missense Mutation (SNP) | VAF 73/80 reads (91%) | SIFT deleterious (0.04); PolyPhen benign (0.265); catalogued as COSV63669355; called by muse, mutect2, varscan2
- GPC6 | c.659C>T p.T220I | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV65527228; called by muse, mutect2, varscan2
- GRIA3 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 47/54 reads (87%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs1350221033, COSV52074130; called by muse, mutect2, varscan2
- GRIN3A | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as rs767070992, COSV62450727; called by muse, mutect2, varscan2
- GRM6 | c.2561G>A p.R854Q | Missense Mutation (SNP) | VAF 56/118 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as rs145110689; called by muse, mutect2, varscan2
- HNF1A | c.1738C>T p.P580S | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.005); catalogued as COSV56568109; called by muse, mutect2, varscan2
- HOXB5 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 52/143 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1251417057, COSV53313881; called by muse, mutect2, varscan2
- HTT | c.2072C>T p.S691L | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs779467594, COSV61866792; called by muse, mutect2, varscan2
- IL27RA | c.1214C>T p.S405F | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as rs1255624130, COSV54602289; called by muse, mutect2, varscan2
- IRAG1 | c.2338G>A p.E780K | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as COSV70212487; called by muse, mutect2, varscan2
- KCNJ3 | c.1294G>A p.D432N | Missense Mutation (SNP) | VAF 49/102 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.439); catalogued as COSV54531931; called by muse, mutect2, varscan2
- KIF1A | c.835G>A p.G279S | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1473143877, COSV57497193; called by muse, mutect2, varscan2
- KRT82 | c.1381C>T p.L461F | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.731); catalogued as rs560033539, COSV57786892, COSV57787495; called by muse, mutect2, varscan2
- LEPR | c.2087G>A p.G696E | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.685); catalogued as COSV60760812; called by muse, mutect2, varscan2
- LMOD1 | c.1306G>C p.E436Q | Missense Mutation (SNP) | VAF 53/74 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66173497, COSV66174057; called by muse, mutect2, varscan2
- LRIF1 | c.922A>G p.K308E | Missense Mutation (SNP) | VAF 42/63 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63898129; called by muse, mutect2, varscan2
- LUC7L2 | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 88/109 reads (81%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV54925184; called by muse, mutect2, varscan2
- LY6D | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.514); catalogued as COSV56661409, COSV56661575; called by muse, mutect2
- MARCO | c.731G>A p.G244E | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV59053635; called by muse, mutect2, varscan2
- MCM7 | c.1607A>T p.H536L | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100385082; called by muse, mutect2, varscan2
- MDM1 | c.1537C>T p.L513F | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57448170; called by muse, mutect2, varscan2
- MDN1 | c.4546C>T p.R1516C | Missense Mutation (SNP) | VAF 23/32 reads (72%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as rs1234920779, COSV65519350, COSV65521119; called by muse, mutect2, varscan2
- METTL16 | c.1622G>A p.R541K | Missense Mutation (SNP) | VAF 4/82 reads (5%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.009); catalogued as COSV54015388; called by muse, mutect2
- MFSD6L | c.713C>T p.S238F | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.168); catalogued as COSV61004837; called by muse, mutect2, varscan2
- MGA | c.5570C>T p.S1857L (on ENST00000219905 / NM_001164273.1; = p.S1648L on NM_001080541.2) | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.978); catalogued as rs764277967, COSV54951198; called by muse, mutect2, varscan2
- MICAL3 | c.1438C>T p.R480W | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs772325583, COSV52902784; called by muse, mutect2, varscan2
- MISP | c.793C>T p.P265S | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.208); catalogued as COSV53121691; called by muse, mutect2, varscan2
- MRAP2 | c.208A>T p.T70S | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.996); catalogued as COSV57633962; called by muse, mutect2, varscan2
- MROH2B | c.4498G>A p.E1500K | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); catalogued as COSV101270938, COSV68186181; called by muse, mutect2, varscan2
- MTA1 | c.956C>T p.S319L | Missense Mutation (SNP) | VAF 78/167 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs1555431463, COSV58759341; called by muse, mutect2, varscan2
- MTMR4 | c.2029C>T p.P677S | Missense Mutation (SNP) | VAF 55/107 reads (51%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0); catalogued as COSV60202444; called by muse, mutect2, varscan2
- MTNR1A | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 61/145 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV56157221; called by muse, mutect2, varscan2
- MTSS2 | c.1189G>A p.D397N | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.722); catalogued as rs1204750737, COSV99851947; called by muse, mutect2, varscan2
- MUC16 | c.30889G>A p.A10297T | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.015); catalogued as COSV67482467; called by muse, mutect2, varscan2
- MUC16 | c.29087G>A p.G9696E | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); catalogued as COSV67482472; called by muse, mutect2, varscan2
- MUC5B | c.11108C>T p.T3703I | Missense Mutation (SNP) | VAF 105/228 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV71594400; called by muse, mutect2, varscan2
- MYH2 | c.4385G>A p.W1462* | Nonsense Mutation (SNP) | VAF 20/47 reads (43%) | catalogued as COSV55444965; called by muse, mutect2, varscan2
- MYH2 | c.3881C>T p.S1294L | Missense Mutation (SNP) | VAF 29/44 reads (66%) | SIFT tolerated (0.19); PolyPhen benign (0.061); catalogued as COSV55444973; called by muse, mutect2, varscan2
- MYH3 | c.5240G>A p.R1747K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV56868483; called by muse, mutect2, varscan2
- MYO18A | c.4507G>A p.E1503K | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.433); catalogued as COSV100572757, COSV62871346; called by muse, mutect2, varscan2
- MYOM3 | c.1670C>T p.S557F | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759137598, COSV58390934; called by muse, mutect2, varscan2
- MYPN | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 18/23 reads (78%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1454105180, COSV62737006; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NCAN | c.2941G>A p.E981K | Missense Mutation (SNP) | VAF 54/115 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1415747602, COSV53055790; called by muse, mutect2, varscan2
- NFE2 | c.659G>A p.G220E | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.973); catalogued as rs772353922, COSV56456302, COSV56456725; called by muse, mutect2, varscan2
- NIBAN3 | c.1646A>G p.K549R | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.57); PolyPhen benign (0.131); catalogued as COSV56312437; called by muse, mutect2, varscan2
- NOP2 | c.443C>T p.S148F (on ENST00000322166 / NM_001258308.2; = p.S144F on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.234); catalogued as COSV58907835; called by muse, mutect2, varscan2
- NTSR1 | c.1169G>C p.R390T | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.081); catalogued as COSV65139301; called by muse, mutect2, varscan2
- NUP98 | c.2272G>A p.G758R | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61436471; called by muse, mutect2, varscan2
- OBSL1 | c.3364G>A p.E1122K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54706842; called by muse, mutect2, varscan2
- OR14A16 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.085); catalogued as COSV62926428; called by muse, mutect2, varscan2
- OR1A1 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.92); PolyPhen benign (0.007); catalogued as rs1350313742, COSV58404407; called by muse, mutect2, varscan2
- OR2M2 | c.906G>A p.M302I | Missense Mutation (SNP) | VAF 160/268 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV62898471, COSV62899089; called by muse, mutect2, varscan2
- OR2T2 | c.687G>A p.M229I | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.163); catalogued as COSV61618706; called by muse, mutect2, varscan2
- OR52K2 | c.697C>T p.Q233* | Nonsense Mutation (SNP) | VAF 83/170 reads (49%) | catalogued as COSV57834822, COSV57835398; called by muse, mutect2, varscan2
- OR52M1 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs61751908, COSV64173096; called by muse, mutect2, varscan2
- OR5B21 | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.158); catalogued as rs761732311, COSV64482156; called by muse, mutect2, varscan2
- OR6F1 | c.884A>G p.K295R | Missense Mutation (SNP) | VAF 44/160 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.048); catalogued as COSV57468978; called by muse, mutect2, varscan2
- OR8H1 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV57293612, COSV57295361; called by muse, mutect2, varscan2
- OR8K3 | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.25); catalogued as rs867380056, COSV57130753; called by muse, mutect2, varscan2
- OVOL1 | c.296G>A p.G99D | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV60120378; called by muse, mutect2, varscan2
- PCDHA11 | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.015); catalogued as rs781996593, COSV56502100; called by muse, mutect2, varscan2
- PCDHB11 | c.1676C>T p.P559L | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100697120; called by muse, mutect2, varscan2
- PCDHB4 | c.2159C>T p.S720L | Missense Mutation (SNP) | VAF 84/187 reads (45%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.012); catalogued as COSV52023592; called by muse, mutect2, varscan2
- PCDHGA4 | c.980C>T p.S327F | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.936); catalogued as rs768342539, COSV53980110, COSV54022432; called by muse, mutect2, varscan2
- PCSK9 | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs267598660, COSV56160616; called by muse, mutect2, varscan2
- PDCD1 | c.659C>T p.S220F | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as COSV57691893; called by muse, mutect2, varscan2
- PEAK1 | c.4211C>T p.P1404L | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs866859264, COSV56940639; called by muse, mutect2, varscan2
- PEX2 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1323026896, COSV63814032; called by muse, mutect2, varscan2
- PGK2 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as COSV59164943; called by muse, mutect2, varscan2
- PHLDB1 | c.1342C>T p.R448W | Missense Mutation (SNP) | VAF 68/183 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs782520387, COSV61881033; called by muse, mutect2, varscan2
- PIM3 | c.196-1G>T p.X66_splice | Splice Site (SNP) | VAF 10/33 reads (30%) | catalogued as COSV62260065; called by muse, mutect2, varscan2
- PINK1 | c.275G>A p.C92Y | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as CM044242, COSV58632381; called by muse, mutect2, varscan2
- PITX1 | c.611C>T p.S204F | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54762785; called by muse, mutect2, varscan2
- PLCB4 | c.2989G>A p.E997K | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.899); catalogued as COSV53812373; called by muse, mutect2, varscan2
- POLE | c.1175A>G p.D392G | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.275); catalogued as rs878854840, COSV57686906; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLR3B | c.3140T>C p.L1047P | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57282803; called by muse, mutect2, varscan2
- POP7 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 50/198 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV57450103; called by muse, mutect2, varscan2
- PPARG | c.998G>A p.G333D (on ENST00000287820 / NM_015869.5; = p.G303D on NM_005037.7) | Missense Mutation (SNP) | VAF 28/38 reads (74%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV55144570; called by muse, mutect2, varscan2
- PPP3R2 | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62456821; called by muse, mutect2, varscan2
- PRAME | c.1358G>A p.G453D | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV67162277, COSV67162517; called by muse, mutect2, varscan2
- PRKCA | c.779C>T p.S260F | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as COSV52592035; called by muse, mutect2, varscan2
- PRKDC | c.1308G>T p.E436D | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV58059974; called by mutect2, varscan2
- PSMG3 | c.225C>G p.I75M | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.482); catalogued as rs1035962939, COSV52920834; called by muse, mutect2
- RBM12B | c.1051C>T p.R351C | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.637); catalogued as COSV66968346; called by muse, mutect2, varscan2
- RELN | c.990G>C p.Q330H | Missense Mutation (SNP) | VAF 180/262 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100634445; called by muse, mutect2, varscan2
- RELN | c.989A>C p.Q330P | Missense Mutation (SNP) | VAF 178/259 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100634447; called by muse, mutect2, varscan2
- RHBG | c.416C>T p.S139F | Missense Mutation (SNP) | VAF 64/129 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54805559; called by muse, mutect2, varscan2
- RNF220 | c.804G>C p.K268N | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.066); catalogued as COSV62408497; called by muse, mutect2, varscan2
- RNPEP | c.1235C>T p.T412I | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.012); catalogued as COSV55243249; called by muse, mutect2, varscan2
- SAG | c.668C>T p.P223L | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV68591970; called by muse, mutect2, varscan2
- SALL1 | c.1469G>A p.G490E | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51762189; called by muse, mutect2, varscan2
- SAMD14 | c.680C>T p.S227F | Missense Mutation (SNP) | VAF 66/153 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV50304426; called by muse, mutect2, varscan2
- SART1 | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56713124; called by muse, mutect2, varscan2
- SCARF1 | c.2308G>A p.A770T | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.107); catalogued as rs541363286, COSV53960723; called by muse, mutect2, varscan2
- SCUBE1 | c.1168C>T p.P390S | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT tolerated (0.36); PolyPhen benign (0.122); catalogued as COSV62615076; called by muse, mutect2, varscan2
- SEC23B | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.803); catalogued as rs772402564, COSV52722725; called by muse, mutect2, varscan2
- SERPINA7 | c.242C>T p.S81F | Missense Mutation (SNP) | VAF 25/30 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767190744, COSV59666877; called by muse, mutect2, varscan2
- SHROOM3 | c.442C>T p.R148W | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768503568, COSV56027817; called by muse, mutect2, varscan2
- SIPA1L1 | c.3233C>T p.S1078L | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV62172461; called by muse, mutect2, varscan2
- SLC43A3 | c.1007G>A p.G336D | Missense Mutation (SNP) | VAF 85/203 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61451055; called by muse, mutect2, varscan2
- SMAP2 | c.800C>T p.S267F | Missense Mutation (SNP) | VAF 55/136 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV65533343; called by muse, mutect2, varscan2
- SORCS3 | c.2149G>A p.E717K | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT tolerated (0.09); PolyPhen benign (0.165); catalogued as COSV63797267; called by muse, mutect2, varscan2
- ST8SIA3 | c.1028G>A p.G343E | Missense Mutation (SNP) | VAF 16/44 reads (36%) | PolyPhen possibly damaging (0.779); catalogued as COSV60654901; called by muse, mutect2, varscan2
- STOM | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.711); catalogued as rs777660521, COSV54418936; called by muse, mutect2, varscan2
- SULT2A1 | c.636C>G p.N212K | Missense Mutation (SNP) | VAF 48/54 reads (89%) | SIFT deleterious (0.02); PolyPhen benign (0.408); catalogued as COSV55765779; called by muse, mutect2, varscan2
- SYNE1 | c.15907C>T p.R5303W (on ENST00000367255 / NM_182961.4; = p.R5232W on NM_033071.3) | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as rs149215868; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- TET1 | c.5728C>T p.L1910F | Missense Mutation (SNP) | VAF 37/43 reads (86%) | SIFT tolerated (0.09); PolyPhen benign (0.104); catalogued as COSV65387880; called by muse, mutect2, varscan2
- THEMIS | c.1693G>A p.E565K | Missense Mutation (SNP) | VAF 46/78 reads (59%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV64072471; called by muse, mutect2, varscan2
- TM4SF5 | c.396G>A p.A132= | Splice Region (SNP) | VAF 11/42 reads (26%) | catalogued as rs1487505019, COSV54497543; called by muse, mutect2, varscan2
- TMEM151A | c.1375G>A p.G459S | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.125); catalogued as rs756433126, COSV59174641; called by muse, mutect2, varscan2
- TNIK | c.3859G>A p.A1287T | Missense Mutation (SNP) | VAF 19/24 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52691049; called by muse, mutect2, varscan2
- TPMT | c.386C>T p.S129L | Missense Mutation (SNP) | VAF 38/63 reads (60%) | SIFT tolerated (0.09); PolyPhen benign (0.164); catalogued as COSV59429676; called by muse, mutect2, varscan2
- TPO | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs1558265699, COSV61102078; called by muse, mutect2, varscan2
- TRIM46 | c.1928C>T p.A643V | Missense Mutation (SNP) | VAF 62/121 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.067); catalogued as COSV58117480; called by muse, mutect2, varscan2
- TRIM48 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 128/260 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.618); catalogued as COSV70161001, COSV70161953; called by muse, mutect2, varscan2
- TTC39A | c.1124A>T p.Y375F (on ENST00000447632 / NM_001297665.1; = p.Y340F on NM_001080494.3) | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.4); catalogued as COSV52960431; called by muse, mutect2, varscan2
- TTN | c.64595G>A p.G21532E (on ENST00000591111; = p.G14108E on NM_003319.4) | Missense Mutation (SNP) | VAF 70/165 reads (42%) | PolyPhen possibly damaging (0.88); catalogued as COSV60244263; called by muse, mutect2, varscan2
- TXNRD1 | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.024); catalogued as COSV71221756; called by muse, mutect2
- UBAC2 | c.367G>C p.A123P | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.185); catalogued as COSV63120353; called by muse, mutect2, varscan2
- UBAP2 | c.2849C>T p.P950L | Missense Mutation (SNP) | VAF 137/357 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV54291838; called by muse, mutect2, varscan2
- UCP2 | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.947); catalogued as COSV60105109; called by muse, mutect2, varscan2
- USP28 | c.1165C>T p.P389S | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.893); catalogued as COSV50177361; called by muse, mutect2, varscan2
- USP47 | c.2699C>T p.T900I (on ENST00000399455 / NM_001372095.1; = p.T812I on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.051); catalogued as COSV60466495; called by muse, mutect2, varscan2
- VPS13B | c.9034C>T p.P3012S | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV62152503; called by muse, mutect2, varscan2
- WDR55 | c.1058G>A p.W353* | Nonsense Mutation (SNP) | VAF 6/15 reads (40%) | catalogued as rs1232353241, COSV56908650; called by muse, mutect2, varscan2
- WHRN | c.1535G>A p.G512E | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.185); catalogued as COSV99470517; called by muse, mutect2, varscan2
- WHRN | c.1534G>A p.G512R | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.36); catalogued as rs368452983; called by muse, mutect2, varscan2
- XIRP2 | c.10121C>T p.S3374L (on ENST00000628543; = p.S3549L on NM_152381.6) | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.796); catalogued as COSV54685691; called by muse, mutect2, varscan2
- XRCC1 | c.1048C>T p.R350W | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs754041352, COSV53450081; called by muse, mutect2, varscan2
- ZBED9 | c.2317C>T p.P773S | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.992); catalogued as rs771597767, COSV71729677; called by muse, mutect2, varscan2
- ZNF106 | c.1502C>T p.P501L | Missense Mutation (SNP) | VAF 69/164 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs760082495, COSV55520253; called by muse, mutect2, varscan2
- ZNF181 | c.239C>G p.S80* | Nonsense Mutation (SNP) | VAF 39/115 reads (34%) | catalogued as COSV67627085, COSV67627094, COSV67627346; called by muse, mutect2, varscan2
- ZNF181 | c.509T>G p.L170R | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.797); catalogued as COSV67627102; called by muse, mutect2, varscan2
- ZNF213 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV67728159; called by muse, mutect2, varscan2
- ZNF566 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 86/181 reads (48%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.585); catalogued as COSV67574399; called by muse, mutect2, varscan2
- ZNF567 | c.200C>T p.S67L (on ENST00000536254 / NM_001322913.1; = p.S36L on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.283); catalogued as COSV62446192; called by muse, mutect2, varscan2
- ZNF691 | c.493C>T p.H165Y (on ENST00000372502; = p.H134Y on NM_015911.3) | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65289577; called by muse, mutect2, varscan2
- ZNF793 | c.133G>A p.V45I | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.02); catalogued as rs200037315; called by muse, mutect2, varscan2
- ZNF799 | c.1070G>A p.R357K | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.37); catalogued as COSV104434376, COSV70123195; called by muse, mutect2, varscan2
- ZNF99 | c.22G>A p.D8N | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV68056153; called by muse, mutect2, varscan2
- ZP2 | c.1475C>T p.P492L | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.178); catalogued as rs1567212828, COSV54815821; called by muse, mutect2, varscan2
- ZZEF1 | c.2740C>T p.L914F | Missense Mutation (SNP) | VAF 45/89 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as COSV67557849; called by muse, mutect2, varscan2
- SEC23IP | c.1628A>T p.N543I | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- TRBV24-1 | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 134/190 reads (71%) | SIFT tolerated (0.23); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- TRBV6-1 | c.135T>G p.D45E | Missense Mutation (SNP) | VAF 62/296 reads (21%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ABHD15 | c.1356C>T p.S452= | Silent (SNP) | VAF 43/118 reads (36%) | catalogued as rs763348862, COSV100213041; called by muse, mutect2, varscan2
- ADAM2 | c.2139G>A p.R713= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as rs267601919, COSV55858842; called by muse, mutect2, varscan2
- ALOX15B | c.1323G>A p.L441= | Silent (SNP) | VAF 42/73 reads (58%) | catalogued as COSV66479926; called by muse, mutect2, varscan2
- ARAP2 | c.1269G>A p.Q423= | Silent (SNP) | VAF 39/80 reads (49%) | catalogued as COSV58290282; called by muse, mutect2, varscan2
- ARFRP1 | c.306C>T p.S102= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as COSV53928712; called by muse, mutect2, varscan2
- ASPG | c.825C>T p.T275= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as COSV71934052; called by muse, mutect2, varscan2
- ATP13A2 | c.297C>T p.S99= | Silent (SNP) | VAF 24/45 reads (53%) | catalogued as COSV58702669; called by muse, mutect2, varscan2
- BCL2L10 | c.315G>A p.G105= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV53064703; called by muse, mutect2, varscan2
- CA4 | c.567T>C p.N189= | Silent (SNP) | VAF 38/71 reads (54%) | catalogued as COSV56282281; called by muse, mutect2, varscan2
- CACNA1E | c.4347C>T p.F1449= | Silent (SNP) | VAF 85/148 reads (57%) | catalogued as rs368943151; called by muse, mutect2, varscan2
- CACNA2D4 | c.2205C>T p.P735= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV54950301, COSV54956676; called by muse, mutect2, varscan2
- CBARP | c.84C>T p.P28= (on ENST00000382477; = p.P34= on NM_152769.3) | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as COSV99289678, COSV99289829; called by muse, mutect2, varscan2
- CCDC158 | c.1857G>A p.K619= | Silent (SNP) | VAF 46/118 reads (39%) | catalogued as COSV101187127, COSV66356856; called by muse, mutect2, varscan2
- CCDC65 | c.333G>A p.E111= | Silent (SNP) | VAF 30/76 reads (39%) | catalogued as COSV57197350; called by muse, mutect2, varscan2
- CCNY | c.720C>T p.I240= | Silent (SNP) | VAF 23/39 reads (59%) | catalogued as COSV55189075; called by muse, mutect2, varscan2
- CD163 | c.2811C>T p.S937= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV63135918; called by muse, mutect2, varscan2
- CD93 | c.12C>T p.S4= | Silent (SNP) | VAF 7/9 reads (78%) | catalogued as rs1173000429, COSV55667670; called by muse, mutect2, varscan2
- CDC23 | c.1065G>A p.Q355= | Silent (SNP) | VAF 28/70 reads (40%) | catalogued as rs1227951443, COSV67510354; called by muse, mutect2, varscan2
- CHRNA10 | c.669C>T p.Y223= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV99167225; called by muse, mutect2, varscan2
- CHST8 | c.558G>A p.V186= | Silent (SNP) | VAF 42/91 reads (46%) | catalogued as COSV52861748; called by muse, mutect2, varscan2
- CNTN2 | c.1116G>A p.R372= | Silent (SNP) | VAF 28/134 reads (21%) | catalogued as COSV59348333; called by muse, mutect2, varscan2
- COL20A1 | c.510C>T p.F170= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as rs1407460839, COSV58912591; called by muse, mutect2, varscan2
- COX10 | c.1326C>T p.P442= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as rs776202901, COSV55405407; called by muse, mutect2, varscan2
- CSMD1 | c.8301G>A p.T2767= (on ENST00000520002; = p.T2766= on NM_033225.6) | Silent (SNP) | VAF 25/60 reads (42%) | catalogued as rs765938760, COSV59315997, COSV59328648, COSV59361465; called by muse, mutect2, varscan2
- DSCAM | c.5769C>T p.S1923= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV68032820; called by muse, mutect2, varscan2
- DSCAM | c.3609C>T p.S1203= | Silent (SNP) | VAF 13/137 reads (9%) | catalogued as COSV68029671; called by muse, mutect2, varscan2
- DYNAP | c.453C>T p.S151= (on ENST00000321600; = p.S125= on NM_173629.3) | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as COSV58666771; called by muse, mutect2, varscan2
- EBF2 | c.822C>T p.I274= | Silent (SNP) | VAF 25/68 reads (37%) | catalogued as rs1313952654, COSV68776712; called by muse, mutect2, varscan2
- EVA1C | c.1038C>T p.S346= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV55826002; called by muse, mutect2, varscan2
- EVC2 | c.1183C>T p.L395= | Silent (SNP) | VAF 38/82 reads (46%) | catalogued as COSV60399504; called by muse, mutect2, varscan2
- F5 | c.5625G>A p.K1875= | Silent (SNP) | VAF 32/136 reads (24%) | catalogued as COSV63126532; called by muse, mutect2, varscan2
- FBXO46 | c.1227C>T p.F409= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as COSV58349420; called by muse, mutect2, varscan2
- FER1L6 | c.2205C>T p.I735= | Silent (SNP) | VAF 46/110 reads (42%) | catalogued as rs567278064, COSV67549502; called by muse, mutect2, varscan2
- FIBCD1 | c.648C>T p.P216= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as COSV53394912; called by muse, mutect2, varscan2
- FRG2C | c.786C>T p.F262= | Silent (SNP) | VAF 22/86 reads (26%) | called by muse, mutect2, varscan2
- FRMPD2 | c.1882C>T p.L628= | Silent (SNP) | VAF 40/45 reads (89%) | catalogued as COSV59721804; called by muse, mutect2, varscan2
- GALNT13 | c.1476C>T p.I492= | Silent (SNP) | VAF 37/75 reads (49%) | catalogued as rs747966911, COSV67232582; called by muse, mutect2, varscan2
- GALNT14 | c.1599C>T p.I533= | Silent (SNP) | VAF 27/56 reads (48%) | catalogued as rs774070861, COSV61103357; called by muse, mutect2, varscan2
- GAST | c.120G>A p.R40= | Silent (SNP) | VAF 50/132 reads (38%) | catalogued as rs1555585766, COSV61475773; called by muse, mutect2, varscan2
- GATM | c.1065C>T p.S355= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as COSV67540923; called by muse, mutect2, varscan2
- GPR158 | c.1371G>A p.T457= | Silent (SNP) | VAF 15/20 reads (75%) | catalogued as rs1175352427, COSV100892907, COSV66264628; called by muse, mutect2, varscan2
- GRID2 | c.432C>T p.L144= | Silent (SNP) | VAF 42/94 reads (45%) | catalogued as rs373952949, COSV56242758; called by muse, mutect2, varscan2
- GRIN2B | c.3396C>T p.F1132= | Silent (SNP) | VAF 32/70 reads (46%) | catalogued as COSV74207135; called by muse, mutect2, varscan2
- GUCY2F | c.2478G>A p.R826= | Silent (SNP) | VAF 48/60 reads (80%) | catalogued as COSV54306460, COSV99485065; called by muse, mutect2, varscan2
- HABP2 | c.546C>T p.F182= | Silent (SNP) | VAF 33/37 reads (89%) | catalogued as COSV63637647; called by muse, mutect2, varscan2
- HDGFL1 | c.132G>A p.G44= | Silent (SNP) | VAF 40/72 reads (56%) | catalogued as COSV57752743, COSV57752826; called by muse, mutect2, varscan2
- HECTD4 | c.5229C>T p.A1743= | Silent (SNP) | VAF 25/53 reads (47%) | catalogued as rs1298061411, COSV66397035; called by muse, mutect2, varscan2
- HEPHL1 | c.2679G>A p.V893= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as rs764407449, COSV59894312; called by muse, mutect2, varscan2
- HIPK2 | c.3216C>T p.S1072= | Silent (SNP) | VAF 176/250 reads (70%) | catalogued as COSV69211120; called by muse, mutect2, varscan2
- HNF4A | c.1083C>T p.F361= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as rs142268325; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- IFIH1 | c.903C>T p.S301= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV55128916; called by muse, mutect2, varscan2
- IGHV1-24 | c.156C>T p.S52= | Silent (SNP) | VAF 90/330 reads (27%) | catalogued as rs553402469; called by muse, mutect2, varscan2
- IGKV1-8 | c.123C>T p.I41= | Silent (SNP) | VAF 68/164 reads (41%) | called by muse, mutect2, varscan2
- IGKV1D-13 | c.207G>A p.L69= | Silent (SNP) | VAF 38/265 reads (14%) | catalogued as rs780664317; called by muse, mutect2, varscan2
- IKZF1 | c.1413C>T p.F471= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV58781292; called by muse, mutect2, varscan2
- INHBA | c.663C>T p.F221= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as rs776370904, COSV54223226; called by muse, mutect2, varscan2
- INHBE | c.261G>A p.G87= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as COSV56988726; called by muse, mutect2, varscan2
- LILRB5 | c.1404C>T p.F468= (on ENST00000449561 / NM_001081442.3; = p.F467= on NM_006840.5) | Silent (SNP) | VAF 39/46 reads (85%) | catalogued as rs139744787, COSV60260024; called by muse, mutect2, varscan2
- LRRC41 | c.1614G>A p.E538= | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as COSV58441552; called by muse, mutect2, varscan2
- LRRC4C | c.1770C>T p.I590= | Silent (SNP) | VAF 46/103 reads (45%) | catalogued as rs372488464; called by muse, mutect2, varscan2
- MAST1 | c.3561C>T p.L1187= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as COSV52252007; called by muse, mutect2, varscan2
- MCM7 | c.1608C>T p.H536= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as rs1319750312, COSV57995041; called by muse, mutect2, varscan2
- MICAL2 | c.5868G>A p.R1956= | Silent (SNP) | VAF 78/159 reads (49%) | catalogued as COSV56287885; called by muse, mutect2, varscan2
- MROH6 | c.1743G>A p.L581= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs545544552, COSV67339784; called by muse, mutect2, varscan2
- MTSS2 | c.1188G>A p.K396= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as COSV99851948; called by muse, mutect2, varscan2
- MYBL2 | c.693C>T p.V231= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as COSV53832345; called by muse, mutect2, varscan2
- MYO15A | c.9180C>T p.I3060= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as rs968105343, COSV52762349; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYO5B | c.3600G>A p.L1200= | Silent (SNP) | VAF 231/534 reads (43%) | catalogued as COSV53226774; called by muse, mutect2, varscan2
- NALCN | c.1638C>T p.S546= | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as COSV51954788; called by muse, mutect2, varscan2
- NOS3 | c.51G>A p.L17= | Silent (SNP) | VAF 27/127 reads (21%) | catalogued as COSV52493912; called by muse, mutect2, varscan2
- NR0B2 | c.246G>A p.Q82= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as COSV54260036; called by muse, mutect2, varscan2
- NR1D1 | c.1236G>A p.K412= | Silent (SNP) | VAF 37/99 reads (37%) | catalogued as COSV52845260; called by muse, mutect2, varscan2
- NRXN3 | c.1833C>T p.I611= (on ENST00000335750 / NM_001330195.2; = p.I238= on NM_004796.6) | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as COSV59786868; called by muse, mutect2, varscan2
- NUAK2 | c.30C>T p.S10= | Silent (SNP) | VAF 4/69 reads (6%) | called by muse, mutect2
- NYAP2 | c.897C>T p.P299= | Silent (SNP) | VAF 29/59 reads (49%) | catalogued as COSV56013125; called by muse, mutect2, varscan2
- OAS2 | c.414C>T p.I138= | Silent (SNP) | VAF 28/63 reads (44%) | catalogued as COSV60803830; called by muse, mutect2, varscan2
- OR10J1 | c.588C>T p.I196= | Silent (SNP) | VAF 59/199 reads (30%) | catalogued as COSV71129372; called by muse, mutect2, varscan2
- OR12D3 | c.670C>T p.L224= | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as COSV65829559; called by muse, mutect2, varscan2
- OR13C9 | c.510G>A p.R170= | Silent (SNP) | VAF 35/77 reads (45%) | catalogued as COSV52243199; called by muse, mutect2, varscan2
- OR2A2 | c.921G>A p.K307= | Silent (SNP) | VAF 38/244 reads (16%) | catalogued as rs750007693, COSV68872243; called by muse, mutect2, varscan2
- OR52E6 | c.27C>T p.F9= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as rs759558561, COSV61432908; called by muse, mutect2, varscan2
- OTOGL | c.4960C>T p.L1654= (on ENST00000547103; = p.L1645= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 59/138 reads (43%) | catalogued as COSV54021101; called by muse, mutect2, varscan2
- PAN3 | c.1606T>C p.L536= | Silent (SNP) | VAF 29/70 reads (41%) | catalogued as COSV56706221; called by muse, mutect2, varscan2
- PAPPA2 | c.678C>T p.S226= | Silent (SNP) | VAF 72/114 reads (63%) | catalogued as COSV62783452; called by muse, mutect2, varscan2
- PCDHB13 | c.345C>T p.F115= | Silent (SNP) | VAF 19/115 reads (17%) | catalogued as COSV53392971; called by muse, mutect2, varscan2
- PDCD1 | c.783C>T p.S261= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as rs1011563404, COSV57691886; called by muse, mutect2, varscan2
- PDZD2 | c.6693C>T p.S2231= | Silent (SNP) | VAF 155/390 reads (40%) | catalogued as COSV56868028; called by muse, mutect2, varscan2
- PELP1 | c.1956C>T p.P652= | Silent (SNP) | VAF 28/62 reads (45%) | catalogued as rs868431825, COSV52590881; called by muse, mutect2, varscan2
- PER3 | c.198C>T p.F66= | Silent (SNP) | VAF 27/59 reads (46%) | catalogued as rs375818157; called by muse, mutect2, varscan2
- PRDM15 | c.78C>T p.P26= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as rs770172957, COSV54157390, COSV99520748; called by muse, mutect2, varscan2
- PTPN3 | c.1845C>T p.F615= | Silent (SNP) | VAF 51/88 reads (58%) | catalogued as COSV52709233, COSV52711147; called by muse, mutect2, varscan2
- PTPN7 | c.603G>A p.K201= (on ENST00000495688; = p.K240= on NM_002832.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 40/64 reads (63%) | catalogued as COSV58314062; called by muse, mutect2, varscan2
- PTX4 | c.957G>A p.E319= (on ENST00000447419 / NM_001328608.2; = p.E314= on NM_001013658.1) | Silent (SNP) | VAF 38/85 reads (45%) | catalogued as COSV53518735; called by muse, mutect2, varscan2
- RABGAP1L | c.495C>T p.P165= | Silent (SNP) | VAF 61/254 reads (24%) | catalogued as COSV52315720; called by muse, mutect2, varscan2
- RGL1 | c.1270C>T p.L424= (on ENST00000360851 / NM_001297672.2; = p.L459= on NM_015149.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 78/132 reads (59%) | catalogued as COSV58992315; called by muse, varscan2
- RHOBTB2 | c.1068C>T p.G356= | Silent (SNP) | VAF 36/91 reads (40%) | catalogued as COSV52572572; called by muse, mutect2, varscan2
- RORB | c.1074G>A p.K358= (on ENST00000396204 / NM_001365023.1; = p.K347= on NM_006914.4) | Silent (SNP) | VAF 35/88 reads (40%) | catalogued as COSV65332754, COSV65338141; called by muse, mutect2, varscan2
- RPLP0 | c.903G>A p.K301= | Silent (SNP) | VAF 27/59 reads (46%) | catalogued as COSV56112799, COSV99935375; called by muse, mutect2, varscan2
- RXFP1 | c.133C>T p.L45= | Silent (SNP) | VAF 46/96 reads (48%) | catalogued as COSV57054338; called by muse, mutect2, varscan2
- SALL4 | c.1800C>T p.G600= | Silent (SNP) | VAF 30/59 reads (51%) | catalogued as COSV53851308; called by muse, mutect2, varscan2
- SBK1 | c.939C>T p.L313= | Silent (SNP) | VAF 8/11 reads (73%) | catalogued as COSV59398432; called by muse, mutect2, varscan2
- SELL | c.210C>T p.C70= (on ENST00000650983; = p.C57= on NM_000655.5) | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as COSV52553912; called by muse, mutect2, varscan2
- SERPINB12 | c.897C>T p.F299= | Silent (SNP) | VAF 74/167 reads (44%) | catalogued as COSV54034467; called by muse, mutect2, varscan2
- SGCE | c.1098C>T p.V366= (on ENST00000647096; = p.V330= on NM_003919.3) | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV56019310; called by muse, mutect2, varscan2
- SLC22A6 | c.417C>T p.S139= | Silent (SNP) | VAF 13/25 reads (52%) | catalogued as COSV100842806, COSV64560798; called by muse, mutect2, varscan2
- SLIT1 | c.579C>T p.I193= | Silent (SNP) | VAF 13/15 reads (87%) | catalogued as COSV56595662; called by muse, mutect2, varscan2
- SPATA32 | c.462C>T p.S154= | Silent (SNP) | VAF 37/89 reads (42%) | catalogued as COSV59304631; called by muse, mutect2, varscan2
- STPG4 | c.90C>T p.A30= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as COSV54279884; called by muse, mutect2, varscan2
- SYT7 | c.951G>A p.V317= | Silent (SNP) | VAF 35/81 reads (43%) | catalogued as rs1020732368, COSV55654225; called by muse, mutect2, varscan2
- TGFB3 | c.324C>T p.F108= | Silent (SNP) | VAF 59/130 reads (45%) | catalogued as rs779502039, COSV53168885; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- THRAP3 | c.480C>T p.S160= | Silent (SNP) | VAF 146/364 reads (40%) | catalogued as rs1478876383, COSV63569210; called by muse, mutect2, varscan2
- THSD7B | c.2379C>T p.S793= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV55721190; called by muse, mutect2, varscan2
- TLR10 | c.780C>T p.F260= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV58300352; called by muse, mutect2, varscan2
- TMEM202 | c.33C>T p.F11= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV58983356; called by muse, mutect2, varscan2
- TRAPPC12 | c.849C>T p.I283= | Silent (SNP) | VAF 18/29 reads (62%) | catalogued as rs147425056; called by muse, mutect2, varscan2
- TRPC3 | c.732G>A p.Q244= (on ENST00000379645 / NM_001366479.2; = p.Q171= on NM_003305.2) | Silent (SNP) | VAF 34/70 reads (49%) | catalogued as COSV53372905; called by muse, mutect2, varscan2
- TSHZ2 | c.942G>A p.S314= | Silent (SNP) | VAF 42/91 reads (46%) | catalogued as rs752188288, COSV61590389; called by muse, mutect2, varscan2
- TTN | c.71488C>T p.L23830= (on ENST00000591111; = p.L16406= on NM_003319.4) | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV60244246; called by muse, mutect2, varscan2
- WNK4 | c.1686G>A p.E562= | Silent (SNP) | VAF 76/168 reads (45%) | catalogued as COSV55908477; called by muse, mutect2, varscan2
- ZNF292 | c.4326C>T p.F1442= | Silent (SNP) | VAF 67/92 reads (73%) | catalogued as COSV60544365; called by muse, mutect2, varscan2
- ZNF311 | c.141A>G p.G47= | Silent (SNP) | VAF 24/36 reads (67%) | catalogued as COSV65853280; called by muse, mutect2, varscan2
- ZNF425 | c.1539C>T p.L513= | Silent (SNP) | VAF 15/114 reads (13%) | catalogued as rs373528690; called by muse, mutect2, varscan2
- C1QTNF3 | c.84+177C>T | Intron (SNP) | VAF 65/159 reads (41%) | catalogued as rs752972223, COSV51469546; called by muse, mutect2, varscan2
- FAM183BP | n.1021G>A | RNA (SNP) | VAF 31/79 reads (39%) | catalogued as rs1345186615; called by muse, mutect2, varscan2
- HERC2P3 | n.1146C>T | RNA (SNP) | VAF 8/44 reads (18%) | catalogued as rs1439959295; called by muse, mutect2, varscan2
- HLA-DRB9 | n.258A>G | RNA (SNP) | VAF 77/126 reads (61%) | catalogued as rs775633308; called by muse, mutect2, varscan2
- IGKV1-13 | n.208G>A | RNA (SNP) | VAF 23/86 reads (27%) | called by muse, varscan2
- IL36B | c.261+838G>A | Intron (SNP) | VAF 29/64 reads (45%) | catalogued as COSV99382986; called by muse, mutect2, varscan2
- LINC01600 | n.858C>T | RNA (SNP) | VAF 75/132 reads (57%) | catalogued as rs1197882438; called by muse, mutect2, varscan2
- MASP1 | c.1303+5015G>A | Intron (SNP) | VAF 34/45 reads (76%) | catalogued as COSV56227098; called by muse, mutect2, varscan2
